Somatic mutation profile of tumor specimen BA2024D (aliquot aq-BA2024D) from BEATAML1.0 case 2122, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.5 years (17,724 days).
Specimen BA2024D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc5143e7-198b-4e76-b755-0fd6f4380282.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3018D (Solid Tissue Normal), aliquot aq-BA3018D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c02f3470-fce6-4ce8-a9e1-36023db2a3a8

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNTTIP2 | c.1998G>A p.M666I | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- OR52N1 | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- UPK2 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- XRN1 | c.2380G>T p.A794S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- ZNF114 | c.1193C>A p.A398E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- MFSD9 | c.222T>C p.L74= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- ZNF671 | c.825G>T p.V275= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- SEMA4G | c.*642C>A | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
